Somatic mutation profile of tumor specimen 8495cc54-eb88-40ab-b03f-363edf (aliquot 8495cc54-eb88-40ab-b03f-363edf_D6) from CPTAC case 05CO011, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA.
Specimen 8495cc54-eb88-40ab-b03f-363edf: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a615abcb-d5fe-4819-8ef4-47f2438fa2d9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 36897a83-b98f-45af-955e-a75e47 (Blood Derived Normal), aliquot 36897a83-b98f-45af-955e-a75e47_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/98c19978-2731-46cf-8bc8-0bd9eb622448

The open-access MAF lists 121 somatic variants for this specimen: 76 protein-altering or splice-affecting, 31 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 31, Intron 7, Nonsense Mutation 7, Splice Region 3, RNA 3, In Frame Del 2, Frame Shift Del 2, Frame Shift Ins 2, 5'Flank 2, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.714dup p.N239* | Frame Shift Ins (INS) | VAF 144/322 reads (45%) | catalogued as rs1567549651, COSV52663173, COSV52791488; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ACTL6B | c.544G>A p.G182S | Missense Mutation (SNP) | VAF 78/156 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs773439376; called by muse, mutect2, varscan2
- ARID1A | c.4552C>T p.P1518S | Missense Mutation (SNP) | VAF 106/220 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as COSV61385773; called by muse, mutect2, varscan2
- CACNA1I | c.1886C>T p.T629M | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs552710262; called by muse, mutect2, varscan2
- CALD1 | c.598C>T p.R200* | Nonsense Mutation (SNP) | VAF 17/119 reads (14%) | catalogued as COSV104421103; called by muse, mutect2, varscan2
- CCDC82 | c.394C>T p.Q132* | Nonsense Mutation (SNP) | VAF 111/250 reads (44%) | catalogued as rs749883135; called by muse, mutect2
- CELSR3 | c.1436G>A p.R479H | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as rs1031937400; called by muse, mutect2, varscan2
- CREB5 | c.208G>A p.E70K (on ENST00000357727 / NM_182898.4; = p.E63K on NM_004904.3) | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs937186996, COSV63219223; called by muse, mutect2, varscan2
- CUL1 | c.1231A>T p.M411L | Missense Mutation (SNP) | VAF 19/164 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs539058564; called by muse, mutect2, varscan2
- CUX2 | c.1540G>A p.A514T | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs750912919; called by muse, varscan2
- EEF2 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 244/606 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV58578527; called by muse, mutect2, varscan2
- ESPN | c.2227C>A p.H743N | Missense Mutation (SNP) | VAF 16/380 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as CM142388; called by muse, mutect2
- ITPKC | c.1508G>A p.R503H | Missense Mutation (SNP) | VAF 134/417 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs759457048; called by muse, mutect2, varscan2
- KCNH5 | c.172G>A p.V58I | Missense Mutation (SNP) | VAF 40/59 reads (68%) | SIFT tolerated (0.13); PolyPhen benign (0.078); catalogued as rs1057417977, COSV59758154; called by muse, mutect2, varscan2
- LAMA2 | c.3778G>A p.E1260K | Missense Mutation (SNP) | VAF 83/469 reads (18%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.997); catalogued as rs1363185527; called by muse, mutect2, varscan2
- MAP2 | c.2243C>T p.A748V | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.058); catalogued as COSV99560523; called by muse, mutect2, varscan2
- MAT1A | c.688G>A p.V230M | Missense Mutation (SNP) | VAF 82/451 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as rs767906537, CM1311638, COSV100944441; called by muse, mutect2, varscan2
- MGAM | c.1536G>C p.K512N | Missense Mutation (SNP) | VAF 19/183 reads (10%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as COSV72074602; called by muse, mutect2
- N4BP3 | c.103G>A p.G35R | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs530201685, COSV51064443; called by muse, mutect2, varscan2
- NHSL1 | c.4183G>A p.G1395S | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.047); catalogued as rs1253213091; called by muse, mutect2, varscan2
- PREX2 | c.1463G>A p.R488H | Missense Mutation (SNP) | VAF 24/152 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376775544; called by muse, varscan2
- PSG8 | c.14C>A p.S5* | Nonsense Mutation (SNP) | VAF 48/144 reads (33%) | catalogued as COSV100125980; called by muse, mutect2, varscan2
- RAP2C | c.245A>G p.Y82C | Missense Mutation (SNP) | VAF 30/51 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV61683364; called by mutect2, varscan2
- REEP2 | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 30/156 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.285); catalogued as rs575378976; called by muse, mutect2, varscan2
- RGR | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 128/438 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs142050467, COSV63894665; called by muse, mutect2, varscan2
- RNF150 | c.987G>A p.P329= | Splice Region (SNP) | VAF 20/88 reads (23%) | catalogued as COSV60791401; called by muse, mutect2, varscan2
- SLC6A19 | c.983G>A p.R328H | Missense Mutation (SNP) | VAF 100/737 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs552867213, COSV100443876; called by muse, mutect2, varscan2
- SLC7A9 | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 96/339 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.692); catalogued as rs148334096; called by muse, mutect2, varscan2
- TBC1D22B | c.1274G>A p.R425H | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1379486788, COSV65143328; called by muse, mutect2, varscan2
- TECRL | c.333C>T p.G111= | Splice Region (SNP) | VAF 14/52 reads (27%) | catalogued as rs535849187, COSV67085280; called by muse, mutect2, varscan2
- TIGIT | c.643C>T p.R215W | Missense Mutation (SNP) | VAF 93/202 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.249); catalogued as rs770819863, COSV67328867; called by muse, mutect2, varscan2
- TOPAZ1 | c.156G>C p.M52I | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV59069050; called by muse, mutect2, varscan2
- VNN1 | c.1307T>A p.V436D | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63390229; called by muse, mutect2
- ZBTB48 | c.1550G>A p.G517E | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1317503301; called by muse, mutect2
- ABHD1 | c.836T>C p.L279P | Missense Mutation (SNP) | VAF 35/282 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- ACOXL | c.770C>T p.A257V | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- APC | c.616dup p.T206Nfs*46 | Frame Shift Ins (INS) | VAF 48/224 reads (21%) | called by mutect2, pindel, varscan2
- APC | c.4271del p.P1424Qfs*49 | Frame Shift Del (DEL) | VAF 42/142 reads (30%) | called by mutect2, pindel, varscan2
- BLM | c.2823+1G>A p.X941_splice | Splice Site (SNP) | VAF 24/220 reads (11%) | called by muse, mutect2, varscan2
- BNC1 | c.2360G>A p.S787N | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- C1GALT1C1 | c.777G>A p.M259I | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- COL4A3 | c.4963T>A p.L1655I | Missense Mutation (SNP) | VAF 50/118 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CUL1 | c.1230G>T p.K410N | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.152); called by muse, mutect2
- DNAH7 | c.635_636del p.E212Gfs*5 | Frame Shift Del (DEL) | VAF 22/74 reads (30%) | called by pindel, varscan2
- EGR4 | c.1654C>T p.R552C (on ENST00000545030; = p.R449C on NM_001965.4) | Missense Mutation (SNP) | VAF 141/287 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FAM200A | c.1471A>G p.K491E | Missense Mutation (SNP) | VAF 17/156 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM205BP | n.190+3G>A | Splice Region (SNP) | VAF 26/80 reads (33%) | called by muse, mutect2, varscan2
- FHL5 | c.32G>T p.C11F | Missense Mutation (SNP) | VAF 41/152 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FLRT2 | c.1737C>A p.Y579* | Nonsense Mutation (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2
- GNPTAB | c.3698T>C p.I1233T | Missense Mutation (SNP) | VAF 22/270 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.864); called by muse, mutect2
- GPR141 | c.818C>A p.T273K | Missense Mutation (SNP) | VAF 13/236 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IGKV6-21 | c.8C>T p.P3L | Missense Mutation (SNP) | VAF 32/279 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- KCNJ4 | c.911G>A p.R304H | Missense Mutation (SNP) | VAF 85/511 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIAA1549L | c.2899C>G p.L967V (on ENST00000321505; = p.L1264V on NM_012194.3) | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LAMA4 | c.2998C>T p.P1000S (on ENST00000230538 / NM_001105206.3; = p.P993S on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 101/480 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAGEL2 | c.3051G>C p.L1017F | Missense Mutation (SNP) | VAF 38/188 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- MAP3K1 | c.4370A>G p.H1457R | Missense Mutation (SNP) | VAF 71/361 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- MAP3K10 | c.2828G>T p.S943I | Missense Mutation (SNP) | VAF 55/158 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- OR51I1 | c.477C>A p.F159L | Missense Mutation (SNP) | VAF 122/303 reads (40%) | SIFT tolerated (0.51); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR52E2 | c.184T>G p.F62V | Missense Mutation (SNP) | VAF 18/189 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2
- PAK3 | c.1451G>T p.R484M (on ENST00000262836 / NM_001324328.2; = p.R469M on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 54/147 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- PDLIM4 | c.811G>A p.D271N | Missense Mutation (SNP) | VAF 139/441 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PGD | c.977C>G p.A326G | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- PHIP | c.3083C>T p.P1028L | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PPP1R9A | c.1300C>T p.Q434* | Nonsense Mutation (SNP) | VAF 67/216 reads (31%) | called by muse, mutect2, varscan2
- PRKCG | c.888C>A p.C296* | Nonsense Mutation (SNP) | VAF 141/430 reads (33%) | called by mutect2, varscan2
- PTPRR | c.797A>G p.N266S | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- RBMX | c.557G>T p.G186V | Missense Mutation (SNP) | VAF 35/51 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ROCK2 | c.1576_1578del p.K526del | In Frame Del (DEL) | VAF 9/80 reads (11%) | called by mutect2, pindel, varscan2
- SH3D21 | c.375G>C p.K125N (on ENST00000453908 / NM_001162530.2; = p.K14N on NM_024676.5) | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.922); called by muse, mutect2
- SIK2 | c.2475_2486del p.P829_P832del | In Frame Del (DEL) | VAF 10/81 reads (12%) | called by mutect2, pindel
- SLC12A1 | c.1169C>A p.A390E | Missense Mutation (SNP) | VAF 34/249 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPARCL1 | c.1911C>G p.N637K | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- TBC1D9B | c.1744G>A p.A582T | Missense Mutation (SNP) | VAF 47/244 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM68 | c.173C>A p.A58D | Missense Mutation (SNP) | VAF 49/155 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF292 | c.1438G>T p.E480* | Nonsense Mutation (SNP) | VAF 90/229 reads (39%) | called by mutect2, varscan2
- ADAMTS2 | c.177G>T p.A59= | Silent (SNP) | VAF 41/172 reads (24%) | called by muse, mutect2, varscan2
- B4GALNT3 | c.2445C>T p.T815= | Silent (SNP) | VAF 72/174 reads (41%) | catalogued as rs374891117; called by muse, mutect2, varscan2
- CCDC82 | c.396A>G p.Q132= | Silent (SNP) | VAF 106/247 reads (43%) | catalogued as rs1565324249; called by muse, mutect2, varscan2
- CNDP1 | c.993C>T p.F331= | Silent (SNP) | VAF 49/125 reads (39%) | catalogued as rs532473359, COSV62593364; called by muse, mutect2, varscan2
- COL6A3 | c.2643C>T p.S881= | Silent (SNP) | VAF 56/260 reads (22%) | catalogued as rs550122375; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- DISP3 | c.48G>A p.E16= | Silent (SNP) | VAF 26/108 reads (24%) | catalogued as rs752686812; called by muse, mutect2, varscan2
- EDC4 | c.516C>G p.L172= | Silent (SNP) | VAF 22/131 reads (17%) | catalogued as rs756147302; called by muse, mutect2, varscan2
- ETNPPL | c.81A>G p.A27= | Silent (SNP) | VAF 23/109 reads (21%) | catalogued as rs1329162660; called by muse, mutect2, varscan2
- FBF1 | c.1980G>A p.S660= (on ENST00000586717; = p.S674= on NM_001319193.1) | Silent (SNP) | VAF 97/403 reads (24%) | catalogued as rs745341618, COSV100045094; called by muse, mutect2, varscan2
- GABRB1 | c.843G>A p.T281= | Silent (SNP) | VAF 21/94 reads (22%) | catalogued as rs759198088, COSV99782956; called by muse, mutect2, varscan2
- HMCN1 | c.15126C>T p.T5042= | Silent (SNP) | VAF 101/327 reads (31%) | catalogued as rs148569971; called by muse, mutect2, varscan2
- HNRNPCL2 | c.282C>T p.N94= | Silent (SNP) | VAF 52/144 reads (36%) | catalogued as rs753248047; called by muse, mutect2, varscan2
- IFT52 | c.1041A>G p.P347= | Silent (SNP) | VAF 33/179 reads (18%) | called by muse, mutect2, varscan2
- IGHV4-39 | c.342C>T p.T114= | Silent (SNP) | VAF 136/303 reads (45%) | catalogued as rs748937641; called by mutect2, varscan2
- IL1RL1 | c.1014A>G p.V338= | Silent (SNP) | VAF 13/130 reads (10%) | catalogued as rs1434826506; called by muse, mutect2, varscan2
- KCNK13 | c.1011G>A p.T337= | Silent (SNP) | VAF 98/215 reads (46%) | catalogued as rs764305711, COSV56410221; called by muse, mutect2, varscan2
- MPP2 | c.1449C>T p.A483= (on ENST00000461854 / NM_001278372.2; = p.A459= on NM_005374.5) | Silent (SNP) | VAF 21/126 reads (17%) | catalogued as rs112465779; called by muse, mutect2, varscan2
- MYBPHL | c.615C>T p.I205= | Silent (SNP) | VAF 33/167 reads (20%) | catalogued as rs771724099, COSV100848875, COSV64063030; called by muse, mutect2, varscan2
- NANP | c.537A>T p.V179= | Silent (SNP) | VAF 39/358 reads (11%) | called by muse, mutect2, varscan2
- NEU4 | c.39C>T p.F13= (on ENST00000391969 / NM_001167602.3; = p.F25= on NM_080741.4) | Silent (SNP) | VAF 129/333 reads (39%) | catalogued as rs920176159, COSV57990448; called by muse, mutect2, varscan2
- OR2T33 | c.633C>A p.L211= | Silent (SNP) | VAF 30/536 reads (6%) | catalogued as COSV58818758; called by muse, mutect2
- PANX2 | c.1386C>T p.P462= | Silent (SNP) | VAF 16/133 reads (12%) | catalogued as rs538347741; called by muse, mutect2, varscan2
- PCDHGA3 | c.1497G>A p.A499= | Silent (SNP) | VAF 28/258 reads (11%) | catalogued as COSV99536694; called by muse, mutect2, varscan2
- PCDHGA9 | c.1359T>G p.S453= | Silent (SNP) | VAF 59/254 reads (23%) | catalogued as rs746092761; called by muse, mutect2, varscan2
- PIK3C2B | c.2544G>A p.S848= | Silent (SNP) | VAF 37/148 reads (25%) | catalogued as rs200182202; called by muse, mutect2, varscan2
- PLG | c.2079C>T p.V693= | Silent (SNP) | VAF 71/381 reads (19%) | catalogued as rs1562381366, COSV57516387; called by muse, mutect2, varscan2
- RDH14 | c.223C>A p.R75= | Silent (SNP) | VAF 6/48 reads (13%) | called by mutect2, varscan2
- TBX6 | c.277C>T p.L93= | Silent (SNP) | VAF 23/89 reads (26%) | catalogued as rs965305430; called by muse, mutect2, varscan2
- VCAN | c.5706A>T p.T1902= | Silent (SNP) | VAF 76/382 reads (20%) | called by mutect2, varscan2
- WNT5B | c.753C>T p.S251= | Silent (SNP) | VAF 76/365 reads (21%) | catalogued as rs149693351; called by muse, mutect2, varscan2
- ZNF483 | c.45A>C p.P15= | Silent (SNP) | VAF 34/163 reads (21%) | called by muse, mutect2, varscan2
- CREB3L2 | c.583+147A>C | Intron (SNP) | VAF 19/111 reads (17%) | catalogued as rs963410868; called by muse, mutect2, varscan2
- EXOG | c.163+348T>G | Intron (SNP) | VAF 8/76 reads (11%) | called by muse, varscan2
- FAM197Y1 | n.499T>G | RNA (SNP) | VAF 41/414 reads (10%) | called by muse, mutect2
- LHX1 | chr17:36937109 G>A | 5'Flank (SNP) | VAF 5/15 reads (33%) | catalogued as rs1235921692; called by muse, mutect2, varscan2
- LINC02740 | n.243A>T | RNA (SNP) | VAF 14/92 reads (15%) | catalogued as rs1318938700; called by mutect2, varscan2
- LY6E | c.172+16C>T | Intron (SNP) | VAF 69/210 reads (33%) | called by muse, mutect2, varscan2
- PEX10 | c.*84del | 3'UTR (DEL) | VAF 67/257 reads (26%) | called by mutect2, pindel, varscan2
- PKD1L2 | n.846C>T | RNA (SNP) | VAF 22/107 reads (21%) | catalogued as rs183992941; called by muse, mutect2, varscan2
- SCIN | chr7:12570632 C>T | 5'Flank (SNP) | VAF 18/194 reads (9%) | catalogued as rs1336570420; called by muse, mutect2
- TPI1 | c.227-553_227-552del | Intron (DEL) | VAF 134/311 reads (43%) | called by pindel, varscan2
- UCHL5 | c.629+134G>A | Intron (SNP) | VAF 13/51 reads (25%) | catalogued as rs760970355; called by muse, mutect2, varscan2
- VILL | c.136-32G>A | Intron (SNP) | VAF 32/127 reads (25%) | called by muse, mutect2, varscan2
- ZNF429 | chr19:21541843 A>C | 3'Flank (SNP) | VAF 25/69 reads (36%) | called by muse, mutect2, varscan2
- ZSCAN32 | c.839-990G>C | Intron (SNP) | VAF 20/103 reads (19%) | catalogued as rs1270156040, COSV59234772; called by muse, mutect2, varscan2
